Somatic mutation profile of tumor specimen C3L-02642-03 (aliquot CPT0201710006) from CPTAC case C3L-02642, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.3 years (28,231 days).
Specimen C3L-02642-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7a3c184-20d9-47ce-b1b1-729f90739bff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02642-31 (Blood Derived Normal), aliquot CPT0201790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59989546-4ac4-4048-9500-8ef6c6a5d2ef

The open-access MAF lists 73 somatic variants for this specimen: 50 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 13, Intron 4, 5'UTR 4, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, 3'Flank 1, Splice Region 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.97-19_106del p.X33_splice | Splice Site (DEL) | VAF 108/236 reads (46%) | hotspot (GDC flag); called by mutect2, pindel
- USH2A | c.4957C>T p.R1653* | Nonsense Mutation (SNP) | VAF 131/401 reads (33%) | catalogued as rs754768875, CM080609, COSV100239697; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALS2CL | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 42/498 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.388); catalogued as rs1322671689; called by muse, mutect2
- BEND4 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.925); catalogued as rs1386784441, COSV104438763; called by muse, mutect2, varscan2
- CARD11 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 259/1061 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV62717031; called by muse, mutect2, varscan2
- DOK1 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 133/337 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as COSV51214301; called by muse, mutect2, varscan2
- EEF1A2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as rs1270796428; called by muse, mutect2, varscan2
- GCSAML | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs762465766; called by muse, mutect2, varscan2
- GPRIN2 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as rs782719223; called by muse, mutect2, varscan2
- IGHG3 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 116/525 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.488); catalogued as rs371848750; called by muse, mutect2, varscan2
- IGHM | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 311/608 reads (51%) | SIFT tolerated (0.16); catalogued as rs540603658; called by muse, mutect2, varscan2
- LRP2 | c.9313G>A p.D3105N | Missense Mutation (SNP) | VAF 126/400 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903742434, COSV55554293, COSV55557557; called by muse, mutect2, varscan2
- MAGEL2 | c.2246G>A p.R749H | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100046254; called by muse, mutect2, varscan2
- MAP3K1 | c.1553C>A p.A518E | Missense Mutation (SNP) | VAF 137/440 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV68124045; called by muse, mutect2, varscan2
- MYO9B | c.3671C>G p.A1224G | Missense Mutation (SNP) | VAF 386/1183 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV101261055; called by muse, mutect2, varscan2
- OTOR | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1413277935, COSV55722250, COSV55723260; called by muse, mutect2, varscan2
- PCDHGB4 | c.2044C>G p.L682V | Missense Mutation (SNP) | VAF 211/529 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99547225; called by muse, mutect2, varscan2
- PITPNM2 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 60/662 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs568994551; called by muse, mutect2
- PIWIL1 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as rs868797611, COSV55351731; called by muse, mutect2, varscan2
- RAD21L1 | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1410182511; called by muse, mutect2, varscan2
- RUNX1 | c.919C>T p.R307C (on ENST00000344691 / NM_001001890.3; = p.R334C on NM_001754.5) | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV55889799; called by muse, mutect2, varscan2
- RYR2 | c.3932C>T p.A1311V | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs757471928, COSV63661231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNTG2 | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 34/419 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV57999399; called by muse, mutect2
- ADNP2 | c.420T>A p.N140K | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ANLN | c.1211_1212del p.T404Kfs*39 | Frame Shift Del (DEL) | VAF 75/367 reads (20%) | called by mutect2, pindel, varscan2
- CHAMP1 | c.648G>C p.E216D | Missense Mutation (SNP) | VAF 120/204 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CITED4 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- CNTNAP2 | c.3722C>T p.A1241V | Missense Mutation (SNP) | VAF 84/713 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- COL5A3 | c.4519C>G p.P1507A | Missense Mutation (SNP) | VAF 135/614 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH14 | c.8686A>C p.T2896P (on ENST00000445597; = p.T3699P on NM_001367479.1) | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FLG | c.6970T>A p.S2324T | Missense Mutation (SNP) | VAF 214/514 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- FRY | c.1466G>A p.S489N | Missense Mutation (SNP) | VAF 112/220 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- GRIN1 | c.1260C>G p.C420W | Missense Mutation (SNP) | VAF 56/1036 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- HCK | c.707_708del p.K236Tfs*79 | Frame Shift Del (DEL) | VAF 45/178 reads (25%) | called by mutect2, pindel, varscan2
- HDAC7 | c.971-4C>G | Splice Region (SNP) | VAF 128/413 reads (31%) | called by muse, mutect2, varscan2
- HOXB6 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 201/314 reads (64%) | SIFT tolerated (0.75); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IL20 | c.112A>G p.N38D | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2
- INTS7 | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MTMR6 | c.1836dup p.E613Rfs*13 | Frame Shift Ins (INS) | VAF 44/112 reads (39%) | called by mutect2, pindel
- NOD1 | c.1445A>T p.E482V | Missense Mutation (SNP) | VAF 63/449 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ORM2 | c.476T>C p.F159S | Missense Mutation (SNP) | VAF 85/523 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA2 | c.4424A>G p.D1475G | Missense Mutation (SNP) | VAF 198/586 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN1A | c.4621C>A p.Q1541K (on ENST00000303395 / NM_001202435.3; = p.Q1530K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SENP7 | c.2415dup p.S806* | Frame Shift Ins (INS) | VAF 17/33 reads (52%) | called by mutect2, pindel, varscan2
- SH3BP2 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 191/613 reads (31%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SOX30 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- TGS1 | c.1787T>C p.V596A | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM58 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF135 | c.1244G>A p.C415Y (on ENST00000313434 / NM_001289401.2; = p.C427Y on NM_003436.4) | Missense Mutation (SNP) | VAF 159/449 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN10 | c.2141G>A p.R714H (on ENST00000252463; = p.R769H on NM_032805.3) | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- A4GALT | c.765G>A p.T255= | Silent (SNP) | VAF 232/433 reads (54%) | catalogued as rs755543231; called by muse, mutect2, varscan2
- AC008397.2 | c.633C>T p.D211= | Silent (SNP) | VAF 131/444 reads (30%) | catalogued as rs760869430, COSV53205187; called by muse, mutect2, varscan2
- CDH17 | c.1707C>T p.H569= | Silent (SNP) | VAF 164/519 reads (32%) | catalogued as rs747776380, COSV50332852; called by muse, mutect2, varscan2
- CTSL | c.315G>A p.V105= | Silent (SNP) | VAF 120/451 reads (27%) | catalogued as rs1404331368; called by muse, mutect2, varscan2
- DLX6 | c.673C>T p.L225= | Silent (SNP) | VAF 135/487 reads (28%) | called by muse, mutect2, varscan2
- FER1L6 | c.3843C>T p.D1281= | Silent (SNP) | VAF 44/192 reads (23%) | catalogued as rs374546209, COSV67553537; called by muse, mutect2, varscan2
- ITGAM | c.171C>T p.A57= | Silent (SNP) | VAF 80/226 reads (35%) | called by muse, mutect2, varscan2
- LILRA5 | c.759G>T p.G253= | Silent (SNP) | VAF 111/382 reads (29%) | called by muse, mutect2, varscan2
- LRFN1 | c.2049G>A p.A683= | Silent (SNP) | VAF 73/189 reads (39%) | catalogued as COSV99953466; called by muse, mutect2, varscan2
- SHISA6 | c.1389G>A p.T463= (on ENST00000409168 / NM_001173461.1; = p.T514= on NM_207386.4) | Silent (SNP) | VAF 25/538 reads (5%) | catalogued as rs754992005, COSV69389213; called by muse, mutect2
- TBXAS1 | c.369C>T p.S123= | Silent (SNP) | VAF 234/936 reads (25%) | catalogued as rs372829666; called by muse, mutect2, varscan2
- TERT | c.2019C>T p.P673= | Silent (SNP) | VAF 142/364 reads (39%) | catalogued as rs762941707; ClinVar: likely benign; called by muse, mutect2, varscan2
- USH1G | c.288C>T p.N96= | Silent (SNP) | VAF 200/783 reads (26%) | called by muse, mutect2, varscan2
- APBB1 | c.1388+60C>T | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- ERGIC1 | c.-26G>T | 5'UTR (SNP) | VAF 66/169 reads (39%) | called by muse, mutect2, varscan2
- FKBP6 | c.-171G>A | 5'UTR (SNP) | VAF 40/685 reads (6%) | catalogued as rs1554546634; called by muse, mutect2
- HGFAC | c.1103-135G>A | Intron (SNP) | VAF 127/376 reads (34%) | catalogued as rs746962267, COSV66977066; called by muse, mutect2, varscan2
- IL17B | c.-37G>A | 5'UTR (SNP) | VAF 85/233 reads (36%) | catalogued as rs768281041; called by muse, mutect2, varscan2
- NOP56 | c.3+31C>G | Intron (SNP) | VAF 74/232 reads (32%) | called by muse, mutect2, varscan2
- PPP1R12C | c.322-695A>G | Intron (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- RUNX1 | c.-39G>A | 5'UTR (SNP) | VAF 147/577 reads (25%) | catalogued as COSV100277512; called by muse, mutect2, varscan2
- TPM2 | chr9:35682843 del GTCA | 3'Flank (DEL) | VAF 47/177 reads (27%) | called by mutect2, pindel, varscan2
- ZNF578 | chr19:52451433 C>T | 5'Flank (SNP) | VAF 59/149 reads (40%) | catalogued as rs1327530247, COSV99989646; called by muse, mutect2, varscan2
